Somatic mutation profile of tumor specimen TCGA-BF-A1Q0-01A (aliquot TCGA-BF-A1Q0-01A-21D-A19A-08) from TCGA case TCGA-BF-A1Q0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 80.4 years (29,380 days).
Specimen TCGA-BF-A1Q0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82de97e3-8f4a-47e6-aa72-ee2e16940d4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A1Q0-10A (Blood Derived Normal), aliquot TCGA-BF-A1Q0-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fa69adf-a6fb-4984-8128-d04c079af6a8

The open-access MAF lists 774 somatic variants for this specimen: 493 protein-altering or splice-affecting, 269 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 452, Silent 269, Nonsense Mutation 26, Splice Region 5, Intron 4, Splice Site 4, 5'UTR 3, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 2, RNA 2, Translation Start Site 1.

Variants (750 of 774; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC2 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as rs1555775416, COSV101228867, COSV67266912; ClinVar: likely pathogenic; called by muse, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 23/47 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2, varscan2
- MEF2C | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs1561698356, COSV60926309; ClinVar: pathogenic; called by mutect2, varscan2
- SOS2 | c.800T>G p.M267R | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs797045167, CM1511145, CM154932, COSV53564283, COSV53566429, COSV53566628; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 18/26 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.758T>G p.F253C | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1459991987, COSV60198272; called by muse, mutect2, varscan2
- ABCA6 | c.4324G>A p.G1442S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52636278; called by muse, mutect2, varscan2
- AC136428.1 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 104/268 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV101434967; called by muse, varscan2
- ADAM21 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV50789000, COSV50790869; called by muse, mutect2, varscan2
- ADAM29 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1159109823, COSV63660936; called by muse, mutect2, varscan2
- ADAM29 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.095); catalogued as COSV63660944; called by muse, varscan2
- ADAMTS19 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.259); catalogued as COSV50733658; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4688G>A p.R1563K | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.057); catalogued as COSV54438139; called by muse, mutect2, varscan2
- ADCY1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs372552814; called by mutect2, varscan2
- ADGRG4 | c.8192C>T p.S2731F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54950730; called by muse, mutect2, varscan2
- AGO2 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV55045504; called by muse, mutect2, varscan2
- AHNAK | c.9835C>T p.P3279S | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs1231064664, COSV57205312; called by muse, mutect2, varscan2
- AKAP11 | c.4301T>A p.F1434Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50293111; called by mutect2, varscan2
- ALB | c.831T>G p.C277W | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55736171; called by muse, mutect2, varscan2
- ALDH16A1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as rs771158582, COSV53192846; called by mutect2, varscan2
- ALDH6A1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63245885; called by muse, mutect2, varscan2
- ALDH6A1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV63245890; called by mutect2, varscan2
- ALPG | c.856+1G>A p.X286_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99779269; called by muse, mutect2, varscan2
- ALPK1 | c.2839C>T p.P947S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV99453738; called by muse, mutect2, varscan2
- ALPK1 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV99453743; called by muse, mutect2, varscan2
- AMDHD1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1342331313, COSV57137919, COSV57138679; called by muse, mutect2, varscan2
- ANK2 | c.9631G>A p.E3211K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.003); catalogued as COSV52148568; called by mutect2, varscan2
- ANKLE2 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61708020; called by muse, mutect2, varscan2
- APC | c.6767C>T p.P2256L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV57328015; called by muse, mutect2, varscan2
- APOB | c.4379C>T p.S1460F | Missense Mutation (SNP) | VAF 108/368 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV51925421; called by muse, mutect2, varscan2
- ARHGAP28 | c.1186G>A p.V396M (on ENST00000383472 / NM_001366230.1; = p.V237M on NM_001010000.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as rs761880362, COSV51632404; called by mutect2, varscan2
- ARHGEF12 | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.257); catalogued as COSV63103005; called by muse, mutect2, varscan2
- ARHGEF15 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV62724485; called by muse, mutect2, varscan2
- ARL3 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV53299028; called by muse, mutect2, varscan2
- ARL4D | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV60721313; called by muse, mutect2, varscan2
- ASMT | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67109589; called by muse, varscan2
- ASNS | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs1343428756, COSV51550543; called by muse, varscan2
- ASTN1 | c.3574C>T p.L1192F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as COSV62492158, COSV62502715; called by muse, mutect2, varscan2
- ASTN2 | c.2383C>T p.Q795* (on ENST00000313400 / NM_001365069.1; = p.Q744* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV57755138; called by muse, varscan2
- ASXL3 | c.4933G>A p.E1645K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52458821; called by mutect2, varscan2
- ATF6B | c.2111G>T p.*704Lext*8 | Nonstop Mutation (SNP) | VAF 49/293 reads (17%) | catalogued as COSV64351378, COSV64352050; called by mutect2, varscan2
- ATMIN | c.1486A>T p.S496C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55145290; called by muse, mutect2, varscan2
- ATP12A | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745443085, COSV54512186; called by mutect2, varscan2
- ATP2B1 | c.853G>C p.G285R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53804559; called by muse, mutect2, varscan2
- ATPSCKMT | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54726442; called by mutect2, varscan2
- ATPSCKMT | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99725809; called by mutect2, varscan2
- ATXN7 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV55748549; called by muse, mutect2, varscan2
- AWAT1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV65738248; called by muse, mutect2, varscan2
- B4GALNT2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs147132109, COSV100302810; called by mutect2, varscan2
- BAAT | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV52287458; called by muse, mutect2, varscan2
- BCAS1 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV65084184; called by muse, varscan2
- BCL9 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.435); catalogued as COSV52341592; called by muse, mutect2, varscan2
- BCLAF3 | c.1963G>A p.G655S (on ENST00000379682 / NM_001367774.1; = p.G626S on NM_198279.3) | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV61413264; called by muse, mutect2, varscan2
- BECN1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV64120591; called by muse, varscan2
- BIRC6 | c.7817C>T p.S2606L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV70196140; called by mutect2, varscan2
- BMP15 | c.935C>G p.P312R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53140038, COSV53140732; called by muse, varscan2
- BMP2 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66577125; called by muse, mutect2, varscan2
- BRD8 | c.3559C>T p.H1187Y | Missense Mutation (SNP) | VAF 108/368 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54521998, COSV54522719; called by muse, mutect2, varscan2
- BRWD1 | c.1877T>G p.V626G | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV60893217; called by muse, varscan2
- BTC | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV67547308; called by muse, mutect2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by mutect2, varscan2
- C6orf15 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV52537412; called by muse, varscan2
- CACNA1H | c.6494C>G p.P2165R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs761624506, COSV52352985, COSV52353469; called by mutect2, varscan2
- CACNA2D3 | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55513847; called by muse, mutect2, varscan2
- CAGE1 | c.1172A>G p.N391S (on ENST00000512086; = p.N255S on NM_205864.3) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.242); catalogued as COSV57075006; called by muse, mutect2, varscan2
- CALB1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV55366725; called by muse, mutect2, varscan2
- CBX8 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53935593; called by mutect2, varscan2
- CC2D2A | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs762472063, COSV67502434; called by mutect2, varscan2
- CCDC158 | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.047); catalogued as COSV66355313; called by muse, mutect2, varscan2
- CCDC180 | c.3107T>C p.M1036T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV63827385; called by muse, varscan2
- CCDC68 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61603141; called by mutect2, varscan2
- CCDC93 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 44/182 reads (24%) | catalogued as COSV60119832; called by mutect2, varscan2
- CD180 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV56517021; called by muse, mutect2, varscan2
- CD1E | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV63770174; called by mutect2, varscan2
- CD1E | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV63770184; called by muse, varscan2
- CDH16 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55335133; called by muse, mutect2, varscan2
- CDH19 | c.633A>T p.K211N | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV50954874, COSV50969388; called by mutect2, varscan2
- CDH9 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50254395, COSV50326277; called by mutect2, varscan2
- CDHR2 | c.2140G>A p.G714S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56135207; called by muse, mutect2, varscan2
- CENPE | c.7975C>T p.R2659C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs774765853, COSV54381302; called by mutect2, varscan2
- CENPF | c.1866G>C p.W622C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV65273066, COSV65273078; called by muse, varscan2
- CEP162 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV57617852; called by muse, mutect2, varscan2
- CERS3 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52565578; called by muse, mutect2, varscan2
- CFAP61 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55620911; called by muse, mutect2, varscan2
- CHAD | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV51971533; called by muse, mutect2, varscan2
- CHD9 | c.6062T>C p.V2021A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54608142; called by muse, mutect2, varscan2
- CHL1 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs767212701, COSV56587674; called by mutect2, varscan2
- CHRNB4 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs867376645, COSV55714899; called by muse, mutect2, varscan2
- CLCA1 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs148962584; called by mutect2, varscan2
- CLNK | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV57011480; called by muse, mutect2
- CLPTM1L | c.223T>G p.L75V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as COSV57989557; called by muse, mutect2, varscan2
- CLSTN2 | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs753704000, COSV71718479; called by muse, mutect2, varscan2
- CLVS1 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57971298; called by muse, mutect2, varscan2
- CNKSR1 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.493); catalogued as COSV64162870; called by muse, mutect2, varscan2
- COL14A1 | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV52848310; called by muse, varscan2
- COL1A2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV51953831; called by muse, mutect2, varscan2
- COL6A3 | c.2464G>A p.G822R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99797518; called by muse, varscan2
- COL6A6 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.191); catalogued as rs766329094, COSV62019088; called by muse, mutect2, varscan2
- COPS3 | c.590A>T p.N197I | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV52004182, COSV52004375; called by muse, mutect2, varscan2
- CORO7 | c.2503T>A p.W835R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52028368; called by muse, mutect2, varscan2
- CPT1C | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as COSV54917902; called by muse, mutect2, varscan2
- CPXM2 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs376940141; called by muse, mutect2, varscan2
- CR1 | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100887532, COSV100887629; called by muse, mutect2, varscan2
- CR1 | c.6116C>T p.P2039L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV65459951; called by muse, mutect2, varscan2
- CRB1 | c.2053G>A p.G685R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779069205, COSV66328902; called by mutect2, varscan2
- CREB3L1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV55830449; called by muse, mutect2, varscan2
- CRYBG1 | c.4030G>A p.D1344N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV64811002; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.279); catalogued as COSV59974496; called by muse, mutect2, varscan2
- CSMD1 | c.7358G>A p.G2453E (on ENST00000520002; = p.G2452E on NM_033225.6) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59288522; called by muse, mutect2
- CTC1 | c.3157G>A p.G1053R | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59852289; called by muse, mutect2, varscan2
- CTNND2 | c.1197C>A p.Y399* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV58868892; called by muse, mutect2, varscan2
- CYP11A1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99165962; called by mutect2, varscan2
- CYP2A6 | c.1212C>A p.F404L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV56534031; called by mutect2, varscan2
- CYSLTR2 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as rs758137158, COSV56165271; called by mutect2, varscan2
- DAB2 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV57912689; called by mutect2, varscan2
- DCTN4 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs555308858, COSV101437521, COSV69781821; called by mutect2, varscan2
- DCX | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs892512121, COSV57566410; called by muse, mutect2, varscan2
- DDHD1 | c.826C>A p.P276T (on ENST00000323669; = p.P473T on NM_030637.3) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV60357588; called by mutect2, varscan2
- DDX3Y | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV60176706; called by mutect2, varscan2
- DGAT2 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57175447; called by muse, mutect2, varscan2
- DGKK | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.921); catalogued as COSV65706569; called by muse, mutect2, varscan2
- DIDO1 | c.4451A>C p.K1484T | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56615123; called by muse, mutect2, varscan2
- DLG4 | c.275C>T p.P92L (on ENST00000399506 / NM_001321075.3; = p.P135L on NM_001365.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV100263600; called by mutect2, varscan2
- DLG4 | c.274C>T p.P92S (on ENST00000399506 / NM_001321075.3; = p.P135S on NM_001365.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.436); catalogued as COSV57236926; called by muse, mutect2, varscan2
- DMBT1 | c.6608C>T p.S2203F (on ENST00000338354 / NM_001377530.1; = p.S1446F on NM_004406.3) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as rs952970432, COSV57536329; called by muse, mutect2, varscan2
- DNAH1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV70226876; called by muse, mutect2, varscan2
- DNAH7 | c.1754+1G>A p.X585_splice | Splice Site (SNP) | VAF 49/97 reads (51%) | catalogued as COSV56754048; called by muse, mutect2, varscan2
- DNMT3B | c.2333C>T p.S778L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV52415479; called by mutect2, varscan2
- DOCK10 | c.4375T>G p.L1459V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV51352405; called by muse, mutect2, varscan2
- DOCK3 | c.5300C>T p.P1767L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1355839402, COSV56506092; called by muse, mutect2, varscan2
- DOCK8 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs756707690, COSV66618187, COSV66622542; ClinVar: uncertain significance; called by mutect2, varscan2
- DPYS | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs368802826; called by mutect2, varscan2
- DSCAML1 | c.3130G>A p.A1044T (on ENST00000321322; = p.A984T on NM_020693.4) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58383067; called by muse, varscan2
- DSG4 | c.2043G>A p.W681* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as rs777350612, COSV57388934; called by muse, varscan2
- DZIP3 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as rs147130794; called by muse, varscan2
- E2F1 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV58534542; called by muse, mutect2, varscan2
- EDN3 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.093); catalogued as COSV100284863; called by muse, varscan2
- EDN3 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV100284864; called by muse, varscan2
- EGF | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1198880581, COSV54476217; called by muse, mutect2, varscan2
- ELAPOR1 | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs749318001, COSV64044022, COSV64044341; called by muse, mutect2
- ELAVL2 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56358107; called by mutect2, varscan2
- EMC2 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV55208141; called by muse, mutect2, varscan2
- ENTPD6 | c.306C>G p.Y102* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV61751052; called by mutect2, varscan2
- EPHB1 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs1305200941, COSV67660565, COSV67671744; called by muse, mutect2, varscan2
- ERCC4 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV61310896; called by mutect2, varscan2
- ERVW-1 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.378); catalogued as COSV71259339; called by mutect2, varscan2
- F7 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60645126; called by muse, varscan2
- FABP5 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1190690497, COSV51917146, COSV99793164; called by muse, mutect2
- FADS2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV53897126; called by muse, varscan2
- FAM135B | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV52708436; called by mutect2, varscan2
- FAM151B | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56471923; called by muse, mutect2, varscan2
- FAM153A | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.188); catalogued as COSV100646905; called by mutect2, varscan2
- FAM167A | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as rs753999118, COSV52702762; called by mutect2, varscan2
- FAM83F | c.1454-1G>A p.X485_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as rs942189631, COSV60999579; called by muse, mutect2, varscan2
- FAM91A1 | c.1898A>T p.N633I | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as COSV58235903; called by muse, mutect2, varscan2
- FARP1 | c.1690T>C p.S564P | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV60331170; called by muse, mutect2
- FAT1 | c.4564C>T p.H1522Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV71672244; called by mutect2, varscan2
- FAT4 | c.6646C>T p.P2216S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1427354114, COSV58673691; called by mutect2, varscan2
- FBXW12 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1185736560, COSV56483120; called by muse, mutect2, varscan2
- FKBP8 | c.979C>T p.P327S (on ENST00000222308 / NM_001308373.2; = p.P328S on NM_012181.5) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as COSV55891316; called by muse, mutect2, varscan2
- FLNC | c.7283C>T p.S2428F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.987); catalogued as COSV57951504; called by mutect2, varscan2
- FLT4 | c.3746C>T p.S1249F | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV56100214; called by muse, mutect2, varscan2
- FNDC1 | c.2729G>A p.R910K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); catalogued as COSV51931937; called by muse, mutect2, varscan2
- FOXD4L5 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1025870625, COSV101073020, COSV101073276; called by mutect2, varscan2
- FOXI1 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as COSV60388139; called by muse, varscan2
- FRAS1 | c.6806G>A p.R2269Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs771923121, COSV53593373; ClinVar: uncertain significance; called by mutect2, varscan2
- FREM1 | c.2287G>A p.G763R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101084226; called by muse, mutect2, varscan2
- FRMPD4 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 76/131 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as rs758573701, COSV66211824; called by muse, mutect2, varscan2
- FSIP2 | c.17629G>A p.E5877K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as COSV58079516; called by mutect2, varscan2
- FUT9 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV56142895; called by muse, mutect2, varscan2
- G6PC | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV53830206; called by muse, varscan2
- GALNTL6 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV72489710; called by muse, mutect2, varscan2
- GC | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56735613; called by mutect2, varscan2
- GIMAP4 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55431305; called by mutect2, varscan2
- GJC2 | c.789A>C p.E263D | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64512415; called by muse, mutect2, varscan2
- GLRA1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866265452, CD1210652, COSV51007985; called by muse, mutect2, varscan2
- GNMT | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758305053, COSV55101996; called by mutect2, varscan2
- GPATCH3 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV64651662; called by muse, mutect2, varscan2
- GPR142 | c.1353G>A p.M451I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1352840541, COSV59518730; called by muse, mutect2, varscan2
- GPR50 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs377409392, COSV54437283; called by mutect2, varscan2
- GRB7 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202075956, COSV100485455; called by mutect2, varscan2
- GRIK1 | c.2719A>G p.R907G | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV58711860; called by muse, mutect2, varscan2
- GRIN2A | c.3385C>T p.H1129Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.307); catalogued as COSV58022657; called by muse, varscan2
- GRIN2B | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV74204946; called by muse, mutect2, varscan2
- GUCY1A1 | c.318G>A p.R106= | Splice Region (SNP) | VAF 10/75 reads (13%) | catalogued as COSV56649586; called by muse, mutect2, varscan2
- GUCY1A2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs765520349, COSV56479357, COSV99976720; called by mutect2, varscan2
- H3C8 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.204); catalogued as COSV59952626; called by mutect2, varscan2
- HAUS8 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs774687111, COSV53725398; called by muse, varscan2
- HCN1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868454030, COSV57495992, COSV57527391; called by muse, mutect2, varscan2
- HDAC9 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs948820030, COSV67768057; called by muse, mutect2, varscan2
- HEMGN | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779943930, COSV52325392; called by mutect2, varscan2
- HIVEP3 | c.974C>T p.S325F | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as COSV56010524; called by muse, mutect2, varscan2
- HOXB1 | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 111/174 reads (64%) | catalogued as COSV53316527; called by muse, mutect2, varscan2
- HYDIN | c.3862G>A p.D1288N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.21); catalogued as COSV66830318; called by muse, mutect2, varscan2
- HYDIN | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.54); catalogued as COSV55478731; called by mutect2, varscan2
- IGHV1-2 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs11553007; called by muse, mutect2, varscan2
- IL12RB1 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV59096134; called by muse, mutect2, varscan2
- IL17A | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.102); catalogued as COSV60684004; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs868601059, CM070952, COSV100146690, COSV56250189; called by muse, mutect2, varscan2
- IL7R | c.669T>G p.S223R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100286632, COSV57406284; called by muse, varscan2
- IL7R | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV57406291; called by muse, varscan2
- ITGA5 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53215315; called by muse, mutect2, varscan2
- ITIH2 | c.1234T>A p.S412T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64432149; called by muse, mutect2, varscan2
- ITPR1 | c.6630T>G p.F2210L (on ENST00000354582; = p.F2155L on NM_002222.7) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56971504; called by muse, mutect2
- KANK4 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs1223822426, COSV62985615; called by muse, mutect2, varscan2
- KCNB2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as COSV73049127; called by muse, mutect2, varscan2
- KCNB2 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs764013780, COSV73049004; called by mutect2, varscan2
- KCNH5 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs1386778378, COSV59753775; called by muse, mutect2, varscan2
- KCNIP1 | c.205C>T p.R69* (on ENST00000411494 / NM_001034837.3; = p.R58* on NM_014592.4) | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as rs763897144, COSV61080929; called by mutect2, varscan2
- KCNQ3 | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.027); catalogued as COSV66463771; called by mutect2, varscan2
- KIAA0408 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs142527882, COSV64108504; called by mutect2, varscan2
- KIAA1549 | c.3035C>T p.S1012F | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54307062; called by muse, mutect2, varscan2
- KLHDC7A | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV68769108; called by mutect2, varscan2
- KLHL1 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV64767755, COSV64788264; called by mutect2, varscan2
- KLK3 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58099013, COSV58102857; called by muse, mutect2, varscan2
- KRT74 | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV59770668; called by mutect2, varscan2
- KRT84 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs775867323, COSV99230728, COSV99230821; called by muse, mutect2, varscan2
- KRTAP5-1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV66298774; called by muse, varscan2
- LAMA5 | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV99439327; called by muse, mutect2, varscan2
- LAMB4 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV52714455; called by muse, mutect2, varscan2
- LAMP1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV60210837; called by muse, mutect2, varscan2
- LILRA2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.445); catalogued as COSV52197001; called by muse, mutect2, varscan2
- LILRB2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as rs1407009553, COSV100078930, COSV58743817; called by muse, mutect2, varscan2
- LMO2 | c.439G>A p.D147N (on ENST00000395833 / NM_001142315.2; = p.D216N on NM_005574.4) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57645578; called by muse, mutect2, varscan2
- LPA | c.5557C>T p.P1853S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV60297883; called by muse, mutect2, varscan2
- LRGUK | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs750348362, COSV53634666; called by mutect2, varscan2
- LRIG1 | c.2756G>A p.G919E | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV56237422; called by muse, mutect2, varscan2
- LRIT3 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs757351189, COSV59983361; called by mutect2, varscan2
- LRP1 | c.8302C>T p.H2768Y | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as rs1308096234, COSV54503398; called by mutect2, varscan2
- LRP1 | c.9046G>A p.G3016S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as rs749283705, COSV54503415; called by muse, mutect2, varscan2
- LRP1B | c.8681C>T p.S2894L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV67191715, COSV67217271; called by mutect2, varscan2
- LRRC49 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV53008433; called by muse, mutect2, varscan2
- LRRC4B | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs774640697, COSV65349356; called by mutect2, varscan2
- LRRC7 | c.2378C>T p.P793L (on ENST00000651989 / NM_001370785.2; = p.P760L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.343); catalogued as COSV50416252; called by muse, mutect2, varscan2
- LRRC8A | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52184381; called by muse, mutect2, varscan2
- LURAP1L | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070667, COSV59983756; called by muse, mutect2, varscan2
- LUZP2 | c.104T>A p.F35Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV61196948; called by mutect2, varscan2
- MAEL | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as rs1473417386, COSV63304047; called by muse, mutect2, varscan2
- MAGEC2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs760812827, COSV55998133; called by mutect2, varscan2
- MAGI2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV62637447; called by muse, mutect2, varscan2
- MAJIN | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV57262385; called by muse, varscan2
- MAN1A1 | c.884T>G p.L295R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870351; called by muse, varscan2
- MAPK8IP3 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as COSV51716935; called by muse, mutect2, varscan2
- MASP1 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV51457741; called by muse, mutect2, varscan2
- ME3 | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV62771068; called by muse, mutect2, varscan2
- MEOX1 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59355426, COSV59356745; called by mutect2, varscan2
- METTL22 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); catalogued as COSV50837436; called by muse, mutect2, varscan2
- MKRN3 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.185); catalogued as COSV58808867; called by muse, mutect2, varscan2
- MMRN2 | c.2194G>A p.G732S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as rs1001802359, COSV64400445; called by muse, mutect2, varscan2
- MPPED2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs766911185, COSV63896380; called by mutect2, varscan2
- MROH2B | c.2025C>A p.F675L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV68181678; called by mutect2, varscan2
- MRPL18 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58457662; called by mutect2, varscan2
- MRPS2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as rs1361419262, COSV54092301; called by muse, mutect2, varscan2
- MTMR7 | c.1758G>A p.M586I | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV51663480; called by muse, mutect2, varscan2
- MUC16 | c.35126C>T p.S11709F | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs867582847, COSV67448609; called by muse, mutect2, varscan2
- MUC16 | c.34666G>A p.D11556N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV67448618; called by mutect2, varscan2
- MYH1 | c.4352G>A p.R1451K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV99875557; called by muse, mutect2, varscan2
- MYH2 | c.2108G>A p.G703D | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV55432642; called by muse, mutect2, varscan2
- MYO16 | c.897T>G p.F299L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV51780003; called by muse, varscan2
- MYOZ2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV61084231; called by muse, varscan2
- NAP1L2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65172238; called by muse, mutect2, varscan2
- NCKAP1L | c.2542G>A p.G848S | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53203963; called by muse, varscan2
- NEB | c.15029G>A p.R5010Q | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs781250495, COSV50828547; called by muse, mutect2, varscan2
- NGDN | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as COSV68142013; called by mutect2, varscan2
- NIPSNAP1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.387); catalogued as COSV53341929; called by muse, mutect2, varscan2
- NLRP12 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.152); catalogued as COSV60744103; called by muse, varscan2
- NLRP3 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV60220792; called by muse, mutect2, varscan2
- NLRP5 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs762936568, COSV66768255; called by muse, varscan2
- NLRP8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV52583981; called by mutect2, varscan2
- NOS1 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as COSV57607774; called by muse, mutect2, varscan2
- NPAP1 | c.3365G>C p.C1122S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV61504979; called by muse, varscan2
- NPY2R | c.620G>A p.W207* | Nonsense Mutation (SNP) | VAF 42/118 reads (36%) | catalogued as COSV61527371; called by muse, varscan2
- NR1D2 | c.965T>C p.F322S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56990861; called by muse, varscan2
- NRP1 | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV55160926; called by mutect2, varscan2
- NRXN2 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780408, COSV55453455; ClinVar: uncertain significance; called by mutect2, varscan2
- NUGGC | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58432839; called by muse, mutect2, varscan2
- NUMB | c.1187C>T p.P396L (on ENST00000355058; = p.P385L on NM_003744.5) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61567781; called by muse, mutect2, varscan2
- NUP160 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV65853698; called by muse, varscan2
- NWD1 | c.4292C>T p.S1431F | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.035); catalogued as COSV100342369; called by muse, mutect2, varscan2
- OLFM3 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); catalogued as COSV58796216; called by muse, varscan2
- OR10A4 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs762149736, COSV65841725; called by muse, mutect2, varscan2
- OR10A6 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV59164598; called by mutect2, varscan2
- OR11H4 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59559874, COSV59560660; called by muse, mutect2, varscan2
- OR13C2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV73377657; called by muse, varscan2
- OR13F1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV58250874; called by muse, varscan2
- OR1L8 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1315338696, COSV59185880, COSV59187568; called by muse, mutect2, varscan2
- OR2M5 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV63545804, COSV63546155, COSV99057361; called by mutect2, varscan2
- OR2W3 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV64456203; called by muse, mutect2, varscan2
- OR4A16 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.295); catalogued as COSV59042058, COSV59042504; called by muse, mutect2, varscan2
- OR4K2 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 89/312 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV53848357; called by muse, mutect2, varscan2
- OR4Q3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177294; called by muse, mutect2, varscan2
- OR52I1 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV56167727; called by muse, mutect2, varscan2
- OR8U1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100164153, COSV56414361; called by mutect2, varscan2
- OTOGL | c.6739G>A p.E2247K (on ENST00000547103; = p.E2238K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV54013841; called by mutect2, varscan2
- OTUD6A | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57972709; called by mutect2, varscan2
- PAK3 | c.571G>A p.E191K (on ENST00000262836 / NM_001324328.2; = p.E176K on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.119); catalogued as COSV53270433; called by mutect2, varscan2
- PAPPA | c.3391G>A p.D1131N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.515); catalogued as rs1306684113, COSV60278344; called by mutect2, varscan2
- PBLD | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1458184304, COSV99516075; called by muse, mutect2, varscan2
- PCDHA11 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as rs531014522, COSV56481240; called by muse, mutect2, varscan2
- PCDHGA4 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as rs1421968549, COSV53907421; called by muse, mutect2, varscan2
- PCED1B | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71394934; called by muse, mutect2, varscan2
- PCIF1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1485871983, COSV65026114; called by muse, mutect2, varscan2
- PCLO | c.3112G>A p.A1038T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752290314, COSV61618751; called by muse, mutect2, varscan2
- PCSK1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60733960; called by mutect2, varscan2
- PCSK5 | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV65084491; called by muse, varscan2
- PDE1A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV59516037; called by muse, varscan2
- PDE2A | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV57803207; called by muse, mutect2, varscan2
- PDE4DIP | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57679831; called by muse, mutect2, varscan2
- PHKA1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59802333; called by mutect2, varscan2
- PIK3C2G | c.3350C>T p.S1117L (on ENST00000676171; = p.S1076L on NM_004570.5) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56798975; called by mutect2, varscan2
- PLA2G2F | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV64279790; called by muse, mutect2, varscan2
- PLCB4 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.14); catalogued as COSV53794730; called by muse, mutect2, varscan2
- PLCXD3 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV60615037; called by mutect2, varscan2
- PLEKHA5 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54695275; called by muse, mutect2, varscan2
- PLEKHG5 | c.1801G>A p.E601K (on ENST00000400915 / NM_001042663.3; = p.E564K on NM_020631.6) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV61067770; called by mutect2, varscan2
- PLXNA2 | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV100885341; called by muse, mutect2, varscan2
- POLQ | c.3088T>A p.F1030I | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.079); catalogued as COSV51746981; called by mutect2, varscan2
- POTEE | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV58225609; called by mutect2, varscan2
- PPM1F | c.929T>G p.V310G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54283103; called by muse, mutect2, varscan2
- PPP4R4 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.323); catalogued as COSV58551938; called by muse, mutect2, varscan2
- PPWD1 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54332832, COSV99731569; called by mutect2, varscan2
- PRAG1 | c.2720G>A p.S907N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs1038446642, COSV58157993; called by mutect2, varscan2
- PRAMEF1 | c.432C>G p.H144Q | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.067); catalogued as COSV60006573; called by muse, varscan2
- PRAMEF2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.441); catalogued as COSV53572837; called by muse, mutect2, varscan2
- PRB1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 91/301 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV53702660, COSV53706049; called by muse, mutect2, varscan2
- PRDM9 | c.509-1G>A p.X170_splice | Splice Site (SNP) | VAF 27/153 reads (18%) | catalogued as rs766825981, COSV57003299; called by muse, mutect2, varscan2
- PRKN | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV58205199, COSV99080708; called by muse, mutect2
- PRPS1L1 | c.532G>C p.V178L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV72649827; called by muse, varscan2
- PRR23B | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.049); catalogued as rs753848744, COSV61493221; called by muse, mutect2, varscan2
- PRSS58 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs930692664, COSV73488457; called by muse, varscan2
- PSD4 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs1320306467, COSV55524914; called by mutect2, varscan2
- PSG11 | c.708C>T p.L236= | Splice Region (SNP) | VAF 42/202 reads (21%) | catalogued as COSV60453863; called by muse, varscan2
- PSME3 | c.113T>G p.L38* | Nonsense Mutation (SNP) | VAF 43/182 reads (24%) | catalogued as COSV53198377; called by muse, mutect2, varscan2
- PTCH2 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373037330; called by mutect2, varscan2
- PTPRR | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.395); catalogued as rs1162339248, COSV51725812; called by mutect2, varscan2
- PWP2 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs1326282549, COSV52384205; called by mutect2, varscan2
- PYHIN1 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63721508; called by mutect2, varscan2
- RAG2 | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs772223078, COSV57556582, COSV57556650; called by muse, mutect2, varscan2
- RASGRF1 | c.3584C>T p.T1195I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV67249389; called by muse, mutect2, varscan2
- RBM11 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs767760971, COSV68747974; called by mutect2, varscan2
- RBM47 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV55930714; called by muse, mutect2, varscan2
- RBP3 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as rs782619759; called by muse, mutect2, varscan2
- RESF1 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57020011; called by muse, varscan2
- RFC1 | c.2807C>G p.A936G (on ENST00000381897 / NM_001363496.2; = p.A935G on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV62898536; called by muse, mutect2, varscan2
- RGL4 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs750034976, COSV51943268; called by muse, mutect2, varscan2
- RGS7 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); catalogued as rs772169550, COSV58530462; called by mutect2, varscan2
- RGS7BP | c.400A>C p.M134L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.743); catalogued as COSV61833712; called by muse, mutect2, varscan2
- RIMS2 | c.2414G>A p.R805Q (on ENST00000666250 / NM_001348490.2; = p.R613Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs538104363, COSV51657124; called by muse, mutect2, varscan2
- RIPK4 | c.1456G>A p.G486S (on ENST00000352483; = p.G438S on NM_020639.3) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs1055788509, COSV60185943; called by muse, varscan2
- RNF152 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.982); catalogued as COSV57184114; called by muse, mutect2, varscan2
- RNF214 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV56117816; called by muse, mutect2, varscan2
- RNGTT | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763371848, COSV55646778; called by mutect2, varscan2
- RORB | c.998G>A p.G333E (on ENST00000396204 / NM_001365023.1; = p.G322E on NM_006914.4) | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs267602267, COSV65333261, COSV65340965; called by muse, mutect2, varscan2
- ROS1 | c.2814G>A p.G938= | Splice Region (SNP) | VAF 6/13 reads (46%) | catalogued as COSV63851428; called by muse, mutect2
- RPL26L1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV54199229; called by muse, mutect2, varscan2
- SAMD7 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59417312; called by mutect2, varscan2
- SCN10A | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV101479274, COSV71860455; called by muse, mutect2, varscan2
- SCN11A | c.4366C>T p.P1456S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1423082221, COSV56565185; called by muse, mutect2, varscan2
- SCN11A | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56566608; called by muse, mutect2, varscan2
- SCN4A | c.4387C>T p.R1463C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs774453167, COSV71125774; called by muse, mutect2, varscan2
- SCNN1B | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV56302121; called by muse, mutect2, varscan2
- SEC14L4 | c.57C>T p.F19= | Splice Region (SNP) | VAF 12/48 reads (25%) | catalogued as rs1220178080, COSV55398650; called by muse, mutect2, varscan2
- SEC16A | c.2815C>T p.P939S | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV51522347; called by muse, varscan2
- SEC16A | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.913); catalogued as COSV51522364; called by muse, varscan2
- SERTAD4 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1409230216, COSV65398831; called by muse, mutect2, varscan2
- SERTM1 | c.161T>A p.F54Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as COSV59375792; called by muse, mutect2, varscan2
- SGSM1 | c.1290C>T p.F430= | Splice Region (SNP) | VAF 28/96 reads (29%) | catalogued as rs754998311, COSV68509036; called by mutect2, varscan2
- SHOC1 | c.3551C>T p.S1184L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV59498126; called by mutect2, varscan2
- SI | c.4963C>T p.R1655W | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs760505676, COSV52268101; called by mutect2, varscan2
- SLC17A2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV55350357; called by muse, mutect2, varscan2
- SLC28A1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.909); catalogued as COSV54476890; called by muse, mutect2, varscan2
- SLC35B1 | c.653C>T p.T218I (on ENST00000649906; = p.T181I on NM_005827.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as COSV53602247; called by mutect2, varscan2
- SLC44A5 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100901931, COSV63758984; called by muse, mutect2, varscan2
- SLC4A2 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 45/88 reads (51%) | catalogued as COSV59655896; called by muse, mutect2, varscan2
- SLC6A13 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 61/93 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs995069701, COSV58255396; called by muse, mutect2, varscan2
- SLC6A3 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54361959; called by muse, mutect2, varscan2
- SLFN11 | c.1411A>T p.I471F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs1425068943, COSV57697785; called by muse, mutect2
- SLFN11 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); catalogued as COSV57697797; called by muse, mutect2
- SLIT3 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs777081384, COSV60594871; called by mutect2, varscan2
- SLITRK4 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as rs782356458, COSV62022372; called by mutect2, varscan2
- SOGA3 | c.2522C>T p.T841I | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as COSV64105268, COSV64105923; called by muse, mutect2, varscan2
- SPDEF | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.355); catalogued as COSV65000649; called by muse, mutect2
- SPEF2 | c.3796C>T p.H1266Y | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV61544791; called by mutect2, varscan2
- SPN | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.938); catalogued as rs376900782; called by muse, mutect2, varscan2
- SPPL2C | c.1487T>A p.M496K | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0.261); catalogued as COSV100234008; called by muse, mutect2, varscan2
- SPRY3 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.788); catalogued as COSV57142039; called by mutect2, varscan2
- SPTA1 | c.6178G>A p.E2060K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867954422, COSV63749683; called by mutect2, varscan2
- SQLE | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as rs772917271, COSV56280007; called by muse, mutect2, varscan2
- SSX3 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV100035337, COSV53643122; called by muse, mutect2, varscan2
- ST8SIA2 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 21/79 reads (27%) | PolyPhen probably damaging (1); catalogued as COSV51567290; called by muse, mutect2, varscan2
- STAU1 | c.1183G>A p.G395R (on ENST00000371856 / NM_001319135.1; = p.G314R on NM_004602.3) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs1258222630, COSV61459184; called by muse, mutect2, varscan2
- STC2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773130884, COSV54178524; called by muse, mutect2, varscan2
- STON1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as rs771380585, COSV59126917; called by muse, varscan2
- STXBP5L | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56502221; called by mutect2, varscan2
- SUCO | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs531909897, COSV55262541; called by muse, mutect2, varscan2
- SVEP1 | c.4996G>A p.G1666R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs906822220, COSV100990660; called by muse, mutect2, varscan2
- SYNE1 | c.1814G>A p.R605K (on ENST00000367255 / NM_182961.4; = p.R612K on NM_033071.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV54919978; called by muse, mutect2, varscan2
- SYNPO2L | c.2072G>A p.G691E (on ENST00000394810 / NM_001114133.3; = p.G467E on NM_024875.5) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs764985644, COSV65736200; called by muse, mutect2, varscan2
- SYT10 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV57338119; called by muse, varscan2
- TAF1L | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV54258726; called by muse, mutect2, varscan2
- TAGAP | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV100487372; called by muse, mutect2, varscan2
- TAS1R2 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64743817; called by muse, mutect2, varscan2
- TAS2R5 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as COSV56094486; called by muse, mutect2, varscan2
- TBC1D10A | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.545); catalogued as rs752820539, COSV53162790; called by mutect2, varscan2
- TBC1D14 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.343); catalogued as COSV101298873; called by muse, mutect2, varscan2
- TBC1D5 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 108/197 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV53750580; called by muse, varscan2
- TBC1D5 | c.997A>G p.R333G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53750588; called by muse, mutect2, varscan2
- TENM2 | c.3791C>T p.P1264L (on ENST00000518659 / NM_001122679.2; = p.P1032L on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs777249386, COSV69123788; called by muse, mutect2, varscan2
- TEX15 | c.1531G>A p.E511K (on ENST00000256246; = p.E894K on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267601898, COSV56341254; called by mutect2, varscan2
- TFAP4 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99200044; called by muse, mutect2, varscan2
- TFAP4 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV99200045; called by muse, mutect2, varscan2
- THADA | c.4102C>T p.R1368C | Missense Mutation (SNP) | VAF 88/292 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs780486249, COSV57677163; called by muse, mutect2, varscan2
- THAP12 | c.778T>A p.F260I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99472879; called by mutect2, varscan2
- TKTL1 | c.1425C>G p.D475E | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54211926; called by muse, varscan2
- TLR6 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV67935020; called by muse, mutect2, varscan2
- TM4SF4 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1283774542, COSV59515247; called by mutect2, varscan2
- TM6SF1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV51943270, COSV99034337; called by muse, varscan2
- TMEM119 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV67188300; called by muse, mutect2, varscan2
- TMEM200A | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV51649839; called by mutect2, varscan2
- TMEM59 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52372956; called by muse, varscan2
- TNKS1BP1 | c.4855C>T p.P1619S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV64100183; called by muse, mutect2, varscan2
- TOX2 | c.1451C>T p.S484L (on ENST00000358131 / NM_001098798.2; = p.S460L on NM_032883.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs779716371, COSV57883132; called by mutect2, varscan2
- TPTE | c.1456C>T p.P486S (on ENST00000618007 / NM_199261.4; = p.P468S on NM_199259.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs757759527; called by mutect2, varscan2
- TRHR | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV61233063; called by muse, varscan2
- TRIB1 | c.1109T>C p.F370S | Missense Mutation (SNP) | VAF 110/284 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.893); catalogued as rs992582240, COSV61334294; called by muse, mutect2, varscan2
- TRIM22 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 18/176 reads (10%) | catalogued as rs757635925, COSV66090072; called by mutect2, varscan2
- TRIM48 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV70160943; called by muse, mutect2, varscan2
- TRPC7 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV61453665; called by muse, mutect2, varscan2
- TRPC7 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as rs544029791, COSV61453683; called by mutect2, varscan2
- TSPAN8 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 162/374 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs777192427, COSV56077571; called by muse, varscan2
- TSPOAP1 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.721); catalogued as COSV52105043; called by muse, mutect2, varscan2
- TSSK1B | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as rs772467727, COSV66814936; called by mutect2, varscan2
- TTC37 | c.1055G>C p.C352S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV100706549; called by muse, mutect2, varscan2
- TTLL6 | c.1573C>T p.R525W (on ENST00000393382 / NM_001130918.3; = p.R218W on NM_173623.3) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777169014, COSV100938244, COSV64976384; called by mutect2, varscan2
- TTN | c.31285G>A p.E10429K (on ENST00000591111; = p.E9502K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | PolyPhen probably damaging (0.953); catalogued as rs1335736658, COSV59911564; called by muse, mutect2, varscan2
- TUBAL3 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV66813999; called by muse, mutect2, varscan2
- TULP3 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV68117438; called by muse, mutect2, varscan2
- UBE3C | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.854); catalogued as COSV61951434, COSV61954133; called by mutect2, varscan2
- UBQLN3 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV61163411; called by muse, mutect2, varscan2
- UCN3 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66823797; called by muse, mutect2, varscan2
- UGT2B10 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as rs1376808814, COSV55319032; called by muse, mutect2, varscan2
- ULK4 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.462); catalogued as COSV57200574; called by muse, mutect2, varscan2
- UNC5D | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.365); catalogued as COSV54773292, COSV99773537; called by muse, mutect2
- UNC79 | c.7590G>A p.M2530I (on ENST00000393151 / NM_001346218.2; = p.M2353I on NM_020818.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56376354, COSV56394401; called by muse, mutect2, varscan2
- USF3 | c.6461C>T p.S2154L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57070283; called by mutect2, varscan2
- USH2A | c.12201T>G p.S4067R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV56334137; called by muse, mutect2
- USP29 | c.1352A>C p.N451T | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV54140455; called by muse, mutect2, varscan2
- USP7 | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs1223989524, COSV100784136; called by muse, mutect2, varscan2
- VCAN | c.6932T>G p.V2311G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV54098243; called by mutect2, varscan2
- VPS13C | c.5996C>T p.T1999I (on ENST00000644861 / NM_020821.3; = p.T1956I on NM_017684.5) | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.235); catalogued as COSV51125952; called by muse, mutect2, varscan2
- VSIG10 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV63652327; called by muse, mutect2, varscan2
- VTA1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV62658173; called by muse, mutect2, varscan2
- WDR35 | c.850A>G p.N284D | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV55600805; called by muse, mutect2, varscan2
- XAB2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as rs1205900277, COSV64321301; called by mutect2, varscan2
- XDH | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65147228, COSV65149703; called by muse, mutect2, varscan2
- XDH | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV65147231; called by muse, mutect2, varscan2
- XIRP1 | c.5167G>A p.D1723N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1430391408, COSV61137236; called by muse, mutect2, varscan2
- YTHDC1 | c.1478C>T p.P493L (on ENST00000344157 / NM_001031732.4; = p.P475L on NM_133370.4) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV100704675; called by muse, mutect2, varscan2
- ZBBX | c.1366T>G p.L456V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs375036699; called by muse, mutect2, varscan2
- ZBED9 | c.3853A>G p.S1285G | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.16); catalogued as COSV71729205; called by muse, mutect2
- ZBTB21 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV60403262; called by muse, mutect2, varscan2
- ZEB1 | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV58037731; called by mutect2, varscan2
- ZFAT | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.054); catalogued as rs772711178, COSV64735251; called by mutect2, varscan2
- ZFHX4 | c.304A>C p.N102H | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV50535236; called by muse, mutect2
- ZMAT4 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52691559; called by muse, mutect2, varscan2
- ZMYND15 | c.1724C>T p.S575L (on ENST00000433935 / NM_001136046.3; = p.S536L on NM_032265.2) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV52640106; called by mutect2, varscan2
- ZNF135 | c.637C>T p.P213S (on ENST00000313434 / NM_001289401.2; = p.P225S on NM_003436.4) | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.538); catalogued as COSV57880424; called by muse, mutect2, varscan2
- ZNF234 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70602912; called by muse, mutect2, varscan2
- ZNF300 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV51032118; called by mutect2, varscan2
- ZNF335 | c.1391C>A p.P464H | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100532876; called by muse, varscan2
- ZNF335 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100532878, COSV59821104; called by muse, varscan2
- ZNF425 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV65200692; called by muse, mutect2, varscan2
- ZNF492 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV101513986; called by mutect2, varscan2
- ZNF536 | c.2972C>T p.S991L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs769745400, COSV100835024, COSV62835611; called by mutect2, varscan2
- ZNF75A | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73039571; called by muse, varscan2
- ZNF77 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV58821459; called by muse, mutect2, varscan2
- ZNF804B | c.2911G>A p.G971S | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV60818305; called by muse, mutect2, varscan2
- ZNF98 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.394); catalogued as rs752069036, COSV63334982; called by muse, mutect2, varscan2
- ZSWIM2 | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs867454594, COSV54574040; called by muse, varscan2
- ZXDC | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs1054894584, COSV60445871; called by muse, mutect2, varscan2
- ZYX | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.954); catalogued as COSV59555687; called by muse, mutect2
- ZZEF1 | c.8190C>G p.F2730L | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142020410, COSV67556193; called by muse, varscan2
- ZZEF1 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.816); catalogued as COSV67556197; called by muse, mutect2, varscan2
- ARID2 | c.3647del p.T1216Sfs*27 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- DNAI4 | c.2200_2201delinsG p.Q734Gfs*8 | Frame Shift Del (DEL) | VAF 56/292 reads (19%) | called by pindel, varscan2*
- FCGBP | c.5663C>T p.P1888L | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); called by muse, mutect2
- FN1 | c.4861_4862dup p.S1621Rfs*10 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | called by mutect2, varscan2
- GDF2 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GPR179 | c.6311C>G p.A2104G (on ENST00000621958; = p.A2103G on NM_001004334.4) | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); called by muse, mutect2
- IGHV3-38 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- PTPN23 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PYGL | c.2017dup p.E673Gfs*46 | Frame Shift Ins (INS) | VAF 43/140 reads (31%) | called by mutect2, pindel, varscan2
- TXNL1 | c.618T>G p.F206L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ABCA3 | c.2187G>A p.L729= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as rs746191316, COSV57050095; called by muse, mutect2, varscan2
- ABCA4 | c.5541C>T p.D1847= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV64671456; called by muse, varscan2
- ACSM2A | c.900C>T p.L300= (on ENST00000219054; = p.L221= on NM_001308169.2) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV54582689; called by muse, varscan2
- ADA2 | c.354C>T p.I118= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs548409372, COSV52830537; called by muse, mutect2, varscan2
- ADAMTS18 | c.1380C>T p.I460= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV51399424, COSV51399690; called by mutect2, varscan2
- ADRB2 | c.459C>T p.I153= | Silent (SNP) | VAF 57/128 reads (45%) | catalogued as rs765265791, COSV60005247; called by mutect2, varscan2
- AMOTL2 | c.861C>T p.S287= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs201797225, COSV51437930; called by muse, mutect2, varscan2
- ANK2 | c.11220C>G p.L3740= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs764003728, COSV52148579, COSV52150204, COSV52154015; called by muse, mutect2, varscan2
- ANK3 | c.6804A>G p.E2268= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV55046765; called by muse, mutect2, varscan2
- ANO4 | c.1602C>T p.F534= (on ENST00000392977 / NM_001286615.2; = p.F499= on NM_178826.4) | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs755777158, COSV54587391; called by mutect2, varscan2
- AP4B1 | c.801C>T p.P267= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV56723606; called by muse, mutect2, varscan2
- APOL3 | c.1044C>T p.F348= (on ENST00000349314 / NM_145640.2; = p.F277= on NM_014349.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs1459415008, COSV62579236; called by muse, mutect2, varscan2
- ARFIP2 | c.516C>T p.S172= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1564984180, COSV54446284; called by mutect2, varscan2
- ARHGAP29 | c.642T>G p.T214= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV53109011; called by muse, mutect2, varscan2
- ASB10 | c.600C>T p.L200= (on ENST00000420175 / NM_001142459.2; = p.L185= on NM_080871.4) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99318485; called by mutect2, varscan2
- ATP2C1 | c.2211C>T p.I737= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV60753187; called by mutect2, varscan2
- BAZ2A | c.5007C>G p.A1669= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV51632523; called by muse, varscan2
- BAZ2A | c.3111C>T p.C1037= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs1260156559, COSV51632545; called by muse, mutect2, varscan2
- BNC2 | c.2787C>T p.L929= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as rs774762974, COSV66161355; called by mutect2, varscan2
- BPIFB6 | c.138G>A p.K46= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV62754397; called by muse, mutect2, varscan2
- C9orf131 | c.2466C>T p.F822= | Silent (SNP) | VAF 31/318 reads (10%) | catalogued as COSV56609820; called by muse, mutect2
- CABIN1 | c.3423C>T p.S1141= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV54078437; called by muse, mutect2, varscan2
- CACNA1A | c.1926C>T p.F642= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs772832553, COSV64191195; called by muse, mutect2, varscan2
- CACNA2D3 | c.1014G>A p.L338= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV55518356; called by muse, mutect2
- CASR | c.126T>C p.F42= | Silent (SNP) | VAF 54/97 reads (56%) | catalogued as COSV56134771; called by muse, mutect2, varscan2
- CBLN3 | c.231C>T p.V77= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV52159005; called by mutect2, varscan2
- CDH6 | c.12C>T p.Y4= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV54065150; called by muse, mutect2, varscan2
- CEP131 | c.3012C>T p.F1004= (on ENST00000269392 / NM_001319228.2; = p.F1001= on NM_014984.4) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs139538707; called by mutect2, varscan2
- CHEK2 | c.267C>T p.T89= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV60416597; called by muse, mutect2, varscan2
- CLGN | c.9C>T p.F3= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV57773397; called by muse, mutect2, varscan2
- CNTN5 | c.2466G>A p.K822= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV54285812; called by muse, mutect2
- COL20A1 | c.510C>T p.F170= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1407460839, COSV58912591; called by mutect2, varscan2
- COL4A1 | c.1326G>A p.Q442= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV65422200; called by muse, mutect2, varscan2
- CORIN | c.1068C>T p.I356= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs374710232; called by mutect2, varscan2
- CPN2 | c.1500C>T p.R500= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV60469660; called by muse, mutect2, varscan2
- CRB1 | c.783C>T p.L261= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV66337014, COSV66339635; called by mutect2, varscan2
- CRHR2 | c.993G>A p.G331= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs762538311, COSV59263971; called by muse, mutect2, varscan2
- CUZD1 | c.1599C>T p.S533= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV59025788; called by muse, mutect2, varscan2
- CX3CR1 | c.840G>A p.T280= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as rs777272874, COSV64193237, COSV64194860; called by muse, mutect2, varscan2
- CYP2C19 | c.396G>A p.R132= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV64906971; called by muse, varscan2
- CYP4F2 | c.261C>T p.G87= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as rs762438385, COSV50000354; called by muse, mutect2, varscan2
- DACH1 | c.1629G>A p.L543= (on ENST00000619232 / NM_001366712.1; = p.L491= on NM_080759.6) | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV57491115; called by mutect2, varscan2
- DCN | c.882C>T p.I294= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1223892469, COSV50006183; called by muse, mutect2, varscan2
- DCSTAMP | c.1359C>T p.V453= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV52576439; called by mutect2, varscan2
- DDX60L | c.3105C>T p.F1035= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52709782; called by mutect2, varscan2
- DEFB119 | c.78T>C p.L26= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV53619754; called by muse, mutect2, varscan2
- DGKI | c.1806C>T p.F602= | Silent (SNP) | VAF 87/173 reads (50%) | catalogued as rs999321739, COSV55938590; called by muse, mutect2, varscan2
- DIPK1B | c.405G>A p.R135= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1396585582, COSV63037747; called by muse, mutect2, varscan2
- DIPK2B | c.823C>T p.L275= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV67640915; called by muse, mutect2, varscan2
- DLGAP2 | c.1069T>C p.L357= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs756329748, COSV70094879; called by muse, mutect2, varscan2
- DLL1 | c.1854G>A p.K618= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV64536843; called by muse, mutect2, varscan2
- DNAH2 | c.6588C>T p.I2196= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs754746688, COSV66717133; called by mutect2, varscan2
- DNAH5 | c.4539C>T p.S1513= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs764718901, COSV54207482; called by muse, mutect2, varscan2
- DOCK2 | c.2407C>T p.L803= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs769569435, COSV56944745; called by muse, mutect2, varscan2
- DOCK3 | c.2616G>A p.E872= | Silent (SNP) | VAF 67/208 reads (32%) | catalogued as rs750051185, COSV56506066; called by muse, mutect2, varscan2
- DSC1 | c.2373C>T p.S791= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV57142405, COSV57149609; called by muse, mutect2, varscan2
- DSG1 | c.210C>T p.I70= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs186238458, COSV57133603; called by mutect2, varscan2
- DSP | c.4329G>A p.R1443= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV65791471; called by mutect2, varscan2
- DSP | c.5970C>T p.T1990= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs992636849, COSV101131266, COSV65791474, COSV65796073; called by muse, mutect2, varscan2
- DYNC1H1 | c.6531C>T p.A2177= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV64134795; called by muse, mutect2, varscan2
- EPHX4 | c.1038G>A p.V346= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as rs1384900947, COSV100952678, COSV64888898, COSV64890163; called by mutect2, varscan2
- ERC2 | c.882G>A p.Q294= | Silent (SNP) | VAF 86/445 reads (19%) | catalogued as COSV55604327; called by muse, mutect2, varscan2
- ERCC6 | c.2622C>T p.F874= | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as rs746074690, COSV63388206; called by muse, varscan2
- FAAH | c.732C>T p.F244= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs755370514, COSV99680027; called by muse, varscan2
- FAM71B | c.1602C>T p.I534= | Silent (SNP) | VAF 138/714 reads (19%) | catalogued as COSV57227736; called by mutect2, varscan2
- FAM91A1 | c.199C>T p.L67= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV58235896; called by mutect2, varscan2
- FAT4 | c.12759G>A p.R4253= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV58673710; called by muse, varscan2
- FBXL6 | c.927C>T p.I309= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV57350910; called by mutect2, varscan2
- FBXO42 | c.2061A>G p.E687= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as COSV65044629; called by muse, varscan2
- FCRL1 | c.150C>T p.F50= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV63824057, COSV63826243; called by muse, mutect2, varscan2
- FCRL5 | c.1824G>A p.G608= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs776442047, COSV62511999; called by muse, mutect2, varscan2
- FER1L6 | c.588C>T p.T196= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV67548383; called by muse, mutect2, varscan2
- FGA | c.816A>T p.G272= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV57393511; called by mutect2, varscan2
- FGD2 | c.156G>A p.R52= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV51462489; called by muse, mutect2, varscan2
- FNDC1 | c.1350C>T p.F450= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as COSV51931929; called by mutect2, varscan2
- FRMD7 | c.309G>A p.K103= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV53744881; called by muse, varscan2
- FSTL1 | c.33G>C p.A11= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV55232226, COSV55236996; called by muse, mutect2, varscan2
- GALNT17 | c.1539T>C p.G513= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV61149872, COSV61198098; called by muse, mutect2, varscan2
- GATA2 | c.240C>T p.T80= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs570641046, COSV62003295; called by mutect2, varscan2
- GPR149 | c.1968G>A p.R656= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs759660189, COSV67666022; called by muse, mutect2, varscan2
- GRAMD2B | c.705C>T p.F235= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV53506107; called by muse, mutect2, varscan2
- GRB7 | c.543C>T p.F181= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100485453; called by muse, mutect2, varscan2
- GRIK1 | c.844C>T p.L282= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV58711869; called by muse, varscan2
- GRM5 | c.2016C>T p.I672= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV59593331; called by muse, mutect2, varscan2
- GSDMA | c.1122C>T p.F374= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as rs867925022, COSV52856602; called by muse, mutect2, varscan2
- HECW1 | c.3870G>A p.L1290= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as COSV67823287; called by muse, varscan2
- HEPHL1 | c.2415G>A p.E805= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs372244115; called by mutect2, varscan2
- HPGDS | c.36G>A p.R12= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV54773176; called by muse, mutect2, varscan2
- HTR7 | c.861C>T p.I287= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs763801173, COSV53283442, COSV53285640; called by mutect2, varscan2
- IGBP1P2 | c.243G>A p.L81= | Silent (SNP) | VAF 54/84 reads (64%) | catalogued as COSV53623988; called by muse, varscan2
- IGKV1D-43 | c.147G>A p.Q49= | Silent (SNP) | VAF 22/82 reads (27%) | called by muse, varscan2
- IQCJ-SCHIP1 | c.1314G>A p.K438= (on ENST00000485419 / NM_001197113.1; = p.K362= on NM_014575.3) | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as COSV61839147, COSV61839599, COSV61843001; called by muse, mutect2, varscan2
- IQGAP2 | c.2265G>A p.V755= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV57168819; called by mutect2, varscan2
- ISG20L2 | c.1041C>T p.A347= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV57459507; called by muse, mutect2, varscan2
- ISM2 | c.897C>T p.F299= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV53634115; called by mutect2, varscan2
- ITGB5 | c.478C>T p.L160= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as rs1244080273, COSV56146860; called by muse, varscan2
- JCAD | c.3831G>A p.R1277= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV64758213; called by muse, mutect2, varscan2
- JPH1 | c.414G>A p.R138= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs774015868, COSV60609013; called by muse, varscan2
- KCNK5 | c.540C>T p.F180= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs954748135, COSV63988526; called by mutect2, varscan2
- KCNQ3 | c.1116G>A p.R372= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as COSV66464662; called by muse, mutect2
- KCNT2 | c.2139C>T p.A713= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV54066648; called by muse, mutect2, varscan2
- KDM3B | c.1593C>T p.S531= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV58688421; called by muse, mutect2, varscan2
- KLHL13 | c.438G>A p.R146= | Silent (SNP) | VAF 55/84 reads (65%) | catalogued as COSV53245247; called by muse, mutect2, varscan2
- KLHL17 | c.852C>T p.P284= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1437017500, COSV58531023; called by muse, mutect2, varscan2
- KNG1 | c.612G>A p.T204= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs142183659, COSV99405213; called by mutect2, varscan2
- KRT2 | c.1431C>T p.I477= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as rs1216944632, COSV59009308; called by muse, varscan2
- KRT83 | c.729C>T p.F243= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99531547; called by muse, mutect2, varscan2
- L1CAM | c.1635C>T p.P545= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs1557091792, COSV62827068; called by muse, mutect2, varscan2
- LEPR | c.2391C>T p.I797= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs919896882, COSV60748478; called by muse, varscan2
- LILRA2 | c.711G>A p.G237= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV52197477; called by muse, mutect2, varscan2
- LRRC4C | c.1134C>T p.S378= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV53419170; called by muse, mutect2, varscan2
- M1AP | c.438G>A p.L146= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV51843050; called by muse, mutect2, varscan2
- MAGEA6 | c.750C>T p.F250= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs782585932, COSV61448617, COSV61449289; called by muse, mutect2, varscan2
- MAGEB1 | c.174C>T p.P58= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV66775293, COSV66775926; called by muse, mutect2, varscan2
- MAGEB6B | c.864G>A p.L288= | Silent (SNP) | VAF 41/68 reads (60%) | called by mutect2, varscan2
- MAP2 | c.144C>T p.F48= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs775418071, COSV52282928; called by muse, mutect2, varscan2
- MAP3K5 | c.2238G>A p.E746= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs1246966662, COSV62887471; called by muse, mutect2, varscan2
- MBD5 | c.4002C>T p.I1334= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV68695927; called by muse, varscan2
- MCOLN1 | c.1431C>T p.F477= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs745766983, COSV51174150; called by mutect2, varscan2
- MED12L | c.405C>T p.I135= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV56370220; called by muse, mutect2, varscan2
- MLIP | c.165C>T p.F55= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV51426588; called by muse, mutect2, varscan2
- MMAA | c.36C>T p.F12= | Silent (SNP) | VAF 17/188 reads (9%) | catalogued as COSV55579192; called by muse, mutect2
- MOGAT2 | c.267C>T p.I89= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV52218560; called by muse, varscan2
- MPP3 | c.1080C>T p.S360= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV68197587, COSV68199065; called by muse, mutect2, varscan2
- MRC1 | c.4105T>C p.L1369= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as rs782024524, COSV99519395; called by muse, mutect2, varscan2
- MRGPRX2 | c.453C>T p.V151= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV61673836; called by muse, mutect2, varscan2
- MUC16 | c.31593C>T p.F10531= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as COSV67448627; called by muse, mutect2, varscan2
- MUC16 | c.19119C>T p.T6373= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV67448636; called by muse, varscan2
- MYBBP1A | c.918C>T p.F306= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV54594334; called by muse, mutect2, varscan2
- MYH1 | c.4353G>A p.R1451= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV56844405; called by muse, mutect2, varscan2
- MYH2 | c.4941G>A p.R1647= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV55432633; called by muse, mutect2, varscan2
- MYO15A | c.6645G>A p.A2215= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs770120780, COSV52752731; called by muse, mutect2, varscan2
- NAIP | c.330G>A p.T110= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs770279208, COSV52000636, COSV52001864; called by mutect2, varscan2
- NBPF15 | c.381C>T p.L127= | Silent (SNP) | VAF 38/108 reads (35%) | called by mutect2, varscan2
- NFKB1 | c.219T>G p.S73= (on ENST00000394820 / NM_001382627.1; = p.S74= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56954840; called by muse, mutect2, varscan2
- NLRC4 | c.597C>T p.F199= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs542279142, COSV61591549; called by muse, mutect2, varscan2
- NLRP10 | c.984C>T p.F328= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1473171546, COSV60778892; called by mutect2, varscan2
- NLRP4 | c.2088G>A p.L696= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as COSV56708298; called by mutect2, varscan2
- NLRP5 | c.429G>A p.R143= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV66762463; called by muse, mutect2, varscan2
- NLRP5 | c.3291G>A p.A1097= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs768735027, COSV66762468; called by mutect2, varscan2
- NLRP9 | c.1509C>T p.I503= | Silent (SNP) | VAF 59/174 reads (34%) | catalogued as rs143748392, COSV60460402; called by muse, varscan2
- NPAP1 | c.2193G>A p.G731= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV61504975; called by mutect2, varscan2
- NPFFR2 | c.1203C>T p.Y401= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs538543232, COSV100440247, COSV58146856, COSV58152388; called by muse, varscan2
- NPL | c.588C>T p.F196= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs770649144, COSV51122678; called by muse, mutect2, varscan2
- NR2F1 | c.852C>T p.A284= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs749201458, COSV59067695; called by muse, mutect2, varscan2
- NSUN2 | c.2097C>T p.L699= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs1057838, COSV52952762, COSV52953106; called by mutect2, varscan2
- NTRK3 | c.1185C>T p.F395= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as rs540292255, COSV58111636, COSV58120116; called by muse, mutect2, varscan2
- NUFIP2 | c.1089G>A p.K363= | Silent (SNP) | VAF 77/128 reads (60%) | catalogued as COSV56602303; called by muse, varscan2
- OR13C8 | c.39C>T p.F13= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs758343445, COSV58610595; called by muse, mutect2, varscan2
- OR13H1 | c.852G>A p.L284= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV58547145; called by mutect2, varscan2
- OR14K1 | c.525C>T p.F175= | Silent (SNP) | VAF 34/121 reads (28%) | catalogued as COSV99315096; called by muse, mutect2, varscan2
- OR2Z1 | c.78C>T p.L26= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV60691790; called by muse, varscan2
- OR5P2 | c.891G>A p.L297= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1026299088, COSV61490003; called by mutect2, varscan2
- OR8B4 | c.315C>T p.F105= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1207965227, COSV62069305, COSV62069679; called by muse, mutect2, varscan2
- OTOP2 | c.840C>T p.T280= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV58880837; called by muse, mutect2, varscan2
- PALMD | c.468G>A p.R156= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV54163181; called by muse, mutect2, varscan2
- PANK3 | c.273C>T p.D91= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV53322022; called by muse, mutect2, varscan2
- PAPPA2 | c.2730C>T p.T910= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1173222169, COSV62774021; called by muse, mutect2, varscan2
- PCDHA13 | c.2202G>A p.P734= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as rs1453696477, COSV56481256; called by muse, mutect2, varscan2
- PCDHAC2 | c.1425C>T p.S475= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as COSV53838870; called by muse, varscan2
- PCDHGB3 | c.69T>C p.S23= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs763997500, COSV53907438; called by muse, mutect2, varscan2
- PCLO | c.2910T>G p.P970= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV61618766; called by muse, mutect2
- PDILT | c.1389C>T p.F463= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100199288; called by mutect2, varscan2
- PHLDB3 | c.1125C>T p.L375= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV52668036; called by muse, varscan2
- PITPNM2 | c.333T>A p.I111= | Silent (SNP) | VAF 81/148 reads (55%) | catalogued as COSV54896690; called by muse, mutect2, varscan2
- PKD1L1 | c.1527C>T p.V509= | Silent (SNP) | VAF 65/122 reads (53%) | catalogued as COSV56959052; called by muse, mutect2, varscan2
- PLCB4 | c.2799G>A p.K933= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV53794743, COSV53803736; called by muse, mutect2
- PLXNA4 | c.1074C>T p.F358= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV58126781; called by mutect2, varscan2
- PPARGC1A | c.1056C>T p.S352= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs891275373, COSV53525004; called by mutect2, varscan2
- PPP1R14C | c.432C>T p.I144= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV63172840; called by mutect2, varscan2
- PRAMEF2 | c.669G>A p.K223= | Silent (SNP) | VAF 31/212 reads (15%) | catalogued as COSV53572846; called by muse, mutect2, varscan2
- PRDM16 | c.2763C>T p.S921= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1310673567, COSV54580519, COSV99578377; called by muse, mutect2, varscan2
- PRKAA2 | c.636C>T p.L212= | Silent (SNP) | VAF 38/339 reads (11%) | catalogued as COSV64802296; called by muse, mutect2, varscan2
- PRPF8 | c.2512T>C p.L838= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV59261116; called by muse, mutect2, varscan2
- PSG7 | c.756G>A p.R252= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as rs377182922; called by muse, mutect2, varscan2
- PTPRG | c.1245C>T p.P415= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as rs574073526, COSV55630893; called by muse, mutect2, varscan2
- RAB5B | c.243A>G p.R81= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs763649609, COSV64364660; called by muse, mutect2, varscan2
- RADIL | c.513G>A p.K171= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV68199534; called by muse, varscan2
- RCN3 | c.510G>A p.R170= | Silent (SNP) | VAF 25/201 reads (12%) | catalogued as rs1394204554, COSV54541296; called by muse, mutect2, varscan2
- RIF1 | c.1929G>A p.E643= | Silent (SNP) | VAF 98/164 reads (60%) | catalogued as rs140493456; called by muse, mutect2, varscan2
- RNF213 | c.11472T>C p.R3824= | Silent (SNP) | VAF 98/132 reads (74%) | catalogued as COSV60391619; called by muse, mutect2, varscan2
- RP1L1 | c.1071C>T p.P357= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs201257393; called by muse, varscan2
- RREB1 | c.2773C>T p.L925= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs903822952, COSV58554228; called by muse, mutect2, varscan2
- RYR2 | c.5640G>A p.E1880= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1306252684, COSV63666253; called by muse, mutect2, varscan2
- SAG | c.1140G>A p.E380= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV68590389; called by muse, mutect2, varscan2
- SCAF1 | c.447C>T p.P149= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV62182569; called by muse, varscan2
- SCN1A | c.5271G>A p.G1757= (on ENST00000303395 / NM_001202435.3; = p.G1746= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as COSV57662134; called by muse, varscan2
- SDE2 | c.636C>T p.C212= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV55250091; called by muse, varscan2
- SDR42E1 | c.912C>T p.L304= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1143453, COSV61093838; called by muse, mutect2, varscan2
- SEMA6A | c.1509C>T p.F503= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV56709598; called by muse, mutect2, varscan2
- SENP7 | c.177C>T p.L59= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as rs1012173670, COSV58608665; called by muse, mutect2, varscan2
- SERPINA6 | c.192C>T p.F64= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV58583680; called by mutect2, varscan2
- SETBP1 | c.4347C>T p.F1449= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV56314370; called by mutect2, varscan2
- SFRP1 | c.534C>T p.S178= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV55172305; called by muse, mutect2, varscan2
- SGMS1 | c.438C>T p.F146= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs773593436, COSV62369479; called by mutect2, varscan2
- SGSM1 | c.849G>A p.T283= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs777197976, COSV68509030; called by mutect2, varscan2
- SHLD1 | c.354T>G p.S118= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV57435455; called by muse, mutect2
- SHOC1 | c.4326G>A p.R1442= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV59498113; called by muse, mutect2, varscan2
- SIGLEC12 | c.372G>A p.E124= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV52459807; called by muse, mutect2, varscan2
- SLC2A3 | c.486C>T p.I162= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs150412980; called by mutect2, varscan2
- SLC34A2 | c.1041C>T p.I347= | Silent (SNP) | VAF 65/173 reads (38%) | catalogued as rs756443417, COSV65940847; called by mutect2, varscan2
- SLC6A11 | c.1554C>T p.I518= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as COSV54390420; called by mutect2, varscan2
- SLC6A19 | c.759C>T p.F253= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV58669818, COSV58670875; called by muse, varscan2
- SLC9A2 | c.2394G>A p.S798= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs1216068801, COSV52129301; called by muse, mutect2, varscan2
- SNF8 | c.102C>T p.A34= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV51726002; called by muse, mutect2, varscan2
- SOX6 | c.2319C>T p.L773= (on ENST00000528429 / NM_001145819.2; = p.L746= on NM_017508.3) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV57038508; called by muse, mutect2, varscan2
- SOX7 | c.783C>T p.A261= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs1311542241, COSV58730369; called by muse, mutect2, varscan2
- SP140L | c.630G>A p.R210= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV54741698; called by muse, mutect2, varscan2
- SPATA2 | c.966C>T p.A322= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV56865656; called by muse, mutect2, varscan2
- SPINK13 | c.15C>T p.P5= | Silent (SNP) | VAF 69/167 reads (41%) | catalogued as COSV68241219; called by muse, mutect2, varscan2
- SPTA1 | c.1042C>T p.L348= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV63749686; called by muse, mutect2, varscan2
- SRGAP2 | c.1974C>T p.S658= (on ENST00000624873 / NM_001170637.4; = p.S659= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs564237703, COSV55333914; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.588C>T p.F196= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs757567213, COSV100231403; called by muse, mutect2, varscan2
- STK11 | c.333C>T p.I111= | Silent (SNP) | VAF 71/215 reads (33%) | catalogued as rs1555737428, COSV58820954; ClinVar: likely benign; called by muse, mutect2, varscan2
- STON1 | c.189C>T p.S63= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs372424278; called by muse, varscan2
- STRC | c.4809A>C p.P1603= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV55851936; called by muse, mutect2, varscan2
- SULF2 | c.1107C>T p.I369= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as COSV63414335; called by muse, varscan2
- SULT1C3 | c.312C>T p.F104= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs778210913, COSV61252485; called by mutect2, varscan2
- SVEP1 | c.4584C>T p.I1528= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs370306062, COSV57027561; called by mutect2, varscan2
- SYCP2L | c.960C>T p.I320= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as rs372755931; called by mutect2, varscan2
- SYNCRIP | c.1551C>T p.P517= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1336303438, COSV62286875; called by muse, varscan2
- SYT7 | c.321C>T p.L107= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs917455728, COSV55654193; called by mutect2, varscan2
- TAGAP | c.1011C>A p.A337= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100487375; called by muse, mutect2, varscan2
- TAOK1 | c.543C>T p.S181= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV55588794; called by muse, mutect2, varscan2
- TAS2R60 | c.480C>T p.F160= | Silent (SNP) | VAF 117/231 reads (51%) | catalogued as COSV60330064; called by muse, mutect2, varscan2
- TAS2R60 | c.561C>T p.S187= | Silent (SNP) | VAF 19/228 reads (8%) | catalogued as COSV60330205; called by muse, mutect2
- TBC1D14 | c.288C>T p.I96= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV101298872; called by muse, mutect2, varscan2
- TBX18 | c.1635G>A p.E545= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV63736205; called by muse, mutect2, varscan2
- TCF4 | c.36G>A p.T12= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs373774656, COSV61891489; called by mutect2, varscan2
- TENM1 | c.1884C>T p.C628= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV64426124; called by muse, varscan2
- TENM2 | c.7512C>T p.F2504= (on ENST00000518659 / NM_001122679.2; = p.F2265= on NM_001080428.3) | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as rs865789151, COSV69123796; called by mutect2, varscan2
- TEX12 | c.327C>T p.F109= | Silent (SNP) | VAF 93/185 reads (50%) | catalogued as COSV54783676; called by muse, mutect2, varscan2
- TGFBI | c.375G>A p.T125= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs559129656, COSV59350146; called by mutect2, varscan2
- TGFBR1 | c.1029G>A p.K343= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV66625006; called by muse, mutect2, varscan2
- THAP12 | c.777C>T p.F259= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99472882; called by mutect2, varscan2
- THOC2 | c.3738T>C p.S1246= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- TIPIN | c.345C>T p.F115= | Silent (SNP) | VAF 16/220 reads (7%) | catalogued as COSV56019380; called by muse, mutect2
- TMED9 | c.651C>T p.I217= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as rs781487309, COSV50352587; called by muse, mutect2, varscan2
- TMEM89 | c.154C>T p.L52= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV56570218; called by muse, mutect2, varscan2
- TNFRSF10A | c.546G>A p.T182= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1390363755, COSV55324665; called by mutect2, varscan2
- TNN | c.2628G>A p.K876= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV53431361; called by muse, mutect2, varscan2
- TONSL | c.3315C>T p.L1105= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV68047752; called by muse, mutect2, varscan2
- TRAV12-1 | c.9C>T p.S3= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- TRIB2 | c.324T>C p.S108= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as COSV50223982; called by muse, mutect2, varscan2
- TRIM60 | c.312G>A p.L104= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV61969889; called by mutect2, varscan2
- TRIOBP | c.3252C>T p.P1084= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1186800402, COSV60374270; called by muse, varscan2
- TRIOBP | c.5523C>T p.S1841= (on ENST00000644935 / NM_001039141.3; = p.S128= on NM_007032.5) | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV58525711; called by muse, mutect2, varscan2
- TRPV6 | c.2232G>A p.R744= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs1289715016, COSV100844357, COSV63890800; called by muse, mutect2, varscan2
- TSHZ2 | c.459G>A p.R153= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as COSV61587170; called by muse, varscan2
- TTN | c.16443G>A p.G5481= (on ENST00000591111; = p.G4554= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV59911578; called by muse, varscan2
- UNC5D | c.1860C>T p.I620= | Silent (SNP) | VAF 16/143 reads (11%) | catalogued as COSV54773312, COSV99777437; called by muse, mutect2, varscan2
- VCAN | c.1539C>T p.F513= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs868175912, COSV54098231, COSV99424253, COSV99426657; called by muse, varscan2
- VPS13B | c.7968G>A p.A2656= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs145460276; ClinVar: likely benign; called by mutect2, varscan2
- VWA8 | c.3498C>T p.H1166= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV64994221; called by mutect2, varscan2
- WDR59 | c.1299C>T p.F433= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV50933573; called by mutect2, varscan2
- WDR6 | c.1896C>T p.F632= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV58244090; called by mutect2, varscan2
- WDR72 | c.1974C>T p.A658= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs868704015, COSV64742253; called by muse, mutect2, varscan2
24 further variants in this file (0 protein-altering or splice-affecting, 12 silent, 12 other) are not listed here.
